CCDI case PBCKTE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/452ab4d4-66c2-456f-9871-db64d8ea4777

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Synovial sarcoma, NOS: ICD-O-3 morphology code: 9040/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 12.5 years (4,568 days).

Biospecimens (3 samples)
- Sample 0DVDT9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVDUB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVDUV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
